Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6K0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6K0-01B (Primary Tumor).

[page 1 of 2]
M

(176.0cm 73.4kg BSA: 1.89m²)

Accession

Specimen Date/Time:

DIAGNOSIS

(A) RIGHT PARTIAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA – Moderate to poorly differentiated

Tumor Features:

Gross: Ulcerating

Size: 1.7 cm in largest dimension

Invasion: Present, depth 1.1 cm

Tumor Border: Infiltrative with thin cords < 4 cells

Perineural Invasion: Absent

Vascular Invasion: Absent

Mucosal and deep margins, negative for tumor.

(B) RIGHT NECK DISSECTION, LEVEL I:

Submandibular gland, negative for tumor

Seven lymph nodes, negative for tumor (0/7)

(C) RIGHT NECK CONTENTS, LEVEL II:

One submandibular gland, negative for tumor

Five lymph nodes, negative for tumor (0/5)

(D) RIGHT NECK CONTENTS, LEVEL III:

Eight lymph nodes, negative for tumor (0/8)

GROSS DESCRIPTION

(A) RIGHT PARTIAL GLOSSECTOMY, DOUBLE STITCH TONGUE TIP, SINGLE STITCH RIGHT VENTRAL MARGIN – A partial glossectomy specimen 4.5 x 2.5 x 2 cm. An ulcerating and partially exophytic mass (1.7 x 1.4 x 1.1 cm) is at least 0.5 cm from the deep and mucosal margins. The specimen is serially sectioned from anterior to posterior.

SECTION CODE: A1, frozen section full cross section with closes peripheral and deep margins; A2 – A7, additional sections of tumor from anterior to posterior.

*FS/DX: SQUAMOUS CARCINOMA, MARGINS FREE.

(B) RIGHT NECK DISSECTION, LEVEL I - A submandibular salivary gland (3.5 x 2.0 x 1.0 cm) and multiple lymph nodes are identified.

SECTION CODE: B1, representative salivary gland; B2, one possible lymph node bisected; B3, one possible lymph node bisected; B4, three possible lymph nodes; B5, two possible lymph nodes.

(C) RIGHT NECK CONTENTS, LEVEL II - Multiple possible lymph nodes are identified.

SECTION CODE: C1, possible salivary gland; C2-C4, one possible lymph node bisected per cassette; C5, two possible lymph nodes.

(D) RIGHT NECK CONTENTS, LEVEL III - Multiple lymph nodes are identified

SECTION CODE: D1-D4, one possible lymph node bisected per cassette; D5, three possible lymph nodes.

CLINICAL HISTORY

SNOMED CODES

T-53000, M-43000, M-80703, "Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site Tongue NOS 002.9

JW 8/9/13

[page 2 of 2]
M (176.0cm 73.4kg BSA: 1.89m²)

Accession:
Specimen Date/Time:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 2b1337f4-ac2d-4029-8727-f53dddfc1ff9 (TCGA-CV-A6K0.4BA4D262-78AF-4EF0-8689-2A09BE7585DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).